Somatic mutation profile of tumor specimen C3N-02230-01 (aliquot CPT0214290009) from CPTAC case C3N-02230, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 65.8 years (24,043 days).
Specimen C3N-02230-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08285ab9-9e7e-4dd7-861c-d8a9d30a2d10.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02230-71 (Blood Derived Normal), aliquot CPT0214410002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2e672d7-c719-41ea-a2ac-5c8f3f98009e

The open-access MAF lists 65 somatic variants for this specimen: 43 protein-altering or splice-affecting, 11 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 11, Intron 6, Nonsense Mutation 3, 3'UTR 3, In Frame Del 2, Splice Site 1, RNA 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2236_2250del p.E746_A750del | In Frame Del (DEL) | VAF 91/421 reads (22%) | hotspot (GDC flag); catalogued as rs727504233, COSV51765066, COSV51849442; ClinVar: drug response; called by mutect2, pindel, varscan2
- BTK | c.1463A>T p.E488V | Missense Mutation (SNP) | VAF 67/694 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.704); catalogued as COSV58118040; called by muse, mutect2
- C8B | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 35/522 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.082); catalogued as rs747647469, COSV64776503; called by muse, mutect2
- CGB7 | c.451C>A p.P151T | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs372564670; called by mutect2, varscan2
- CSMD3 | c.8123G>A p.R2708Q | Missense Mutation (SNP) | VAF 160/434 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.375); catalogued as rs772129152, COSV52248220, COSV52330238; called by muse, mutect2, varscan2
- CSMD3 | c.5707G>T p.D1903Y (on ENST00000297405 / NM_001363185.1; = p.D1799Y on NM_052900.3) | Missense Mutation (SNP) | VAF 44/309 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as rs377007830, COSV52102539; called by muse, mutect2, varscan2
- EGFL6 | c.1017G>A p.M339I | Missense Mutation (SNP) | VAF 12/376 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV63632904; called by muse, mutect2
- FAM135B | c.3508A>C p.K1170Q | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV52740893; called by muse, mutect2
- GRIA3 | c.9G>T p.R3S | Missense Mutation (SNP) | VAF 82/622 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV52084722; called by muse, mutect2, varscan2
- OR52B2 | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV73209425; called by muse, mutect2, varscan2
- PRRC2B | c.5293G>A p.V1765I | Missense Mutation (SNP) | VAF 87/373 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs748692207; called by muse, mutect2, varscan2
- RET | c.625G>A p.G209S | Missense Mutation (SNP) | VAF 14/510 reads (3%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.693); catalogued as rs1407201816; ClinVar: uncertain significance; called by muse, mutect2
- RYR3 | c.11252A>G p.N3751S (on ENST00000389232; = p.N3752S on NM_001036.6) | Missense Mutation (SNP) | VAF 8/147 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs896349674; ClinVar: uncertain significance; called by muse, mutect2
- SOX30 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 25/356 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99398662; called by muse, mutect2
- TGM5 | c.748G>A p.A250T (on ENST00000220420 / NM_201631.4; = p.A168T on NM_004245.4) | Missense Mutation (SNP) | VAF 48/520 reads (9%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as rs113766373, COSV99589399; called by muse, mutect2
- TP53 | c.522del p.R174Sfs*73 | Frame Shift Del (DEL) | VAF 101/401 reads (25%) | catalogued as COSV52773028, COSV52839726, COSV53424551; called by mutect2, pindel, varscan2
- WNK3 | c.4418G>C p.S1473T | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV63614818; called by muse, mutect2
- ALKBH5 | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 13/352 reads (4%) | called by muse, mutect2
- ARHGAP29 | c.3481C>T p.Q1161* | Nonsense Mutation (SNP) | VAF 33/490 reads (7%) | called by muse, mutect2
- C4orf54 | c.2296C>T p.P766S | Missense Mutation (SNP) | VAF 12/272 reads (4%) | SIFT tolerated (0.63); PolyPhen benign (0.015); called by muse, mutect2
- CAP2 | c.1350+1G>T p.X450_splice | Splice Site (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- CEP350 | c.2232C>A p.H744Q | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL27A1 | c.3155C>A p.S1052Y | Missense Mutation (SNP) | VAF 44/338 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); called by muse, varscan2
- CPSF2 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.297); called by muse, mutect2
- EGFL6 | c.1018A>T p.K340* | Nonsense Mutation (SNP) | VAF 12/378 reads (3%) | called by muse, mutect2
- FAT1 | c.13002_13010del p.K4335_V4337del | In Frame Del (DEL) | VAF 34/200 reads (17%) | called by mutect2, pindel, varscan2
- GPRASP1 | c.755G>C p.G252A | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); called by muse, mutect2
- HECTD1 | c.2167G>C p.E723Q | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- HUWE1 | c.4035G>A p.M1345I | Missense Mutation (SNP) | VAF 28/542 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.162); called by muse, mutect2
- LAGE3 | c.367T>C p.F123L | Missense Mutation (SNP) | VAF 42/370 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- MACC1 | c.2492T>A p.V831D | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2
- MT1H | c.110G>A p.C37Y | Missense Mutation (SNP) | VAF 36/311 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MXRA5 | c.7861G>T p.A2621S | Missense Mutation (SNP) | VAF 30/970 reads (3%) | SIFT tolerated (0.74); PolyPhen benign (0.007); called by muse, mutect2
- N4BP2L1 | c.617C>A p.S206Y | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.125); called by muse, varscan2
- PPFIA4 | c.1765A>T p.M589L (on ENST00000447715; = p.M590L on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- PRSS53 | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- QSOX2 | c.1849C>T p.P617S | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.031); called by muse, mutect2
- SLCO5A1 | c.560A>T p.Y187F | Missense Mutation (SNP) | VAF 26/514 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2
- SMG5 | c.701G>T p.C234F | Missense Mutation (SNP) | VAF 47/349 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TLNRD1 | c.609C>A p.D203E | Missense Mutation (SNP) | VAF 11/363 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZCCHC18 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 9/209 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2
- ZNF510 | c.315G>C p.W105C | Missense Mutation (SNP) | VAF 10/334 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2
- ZNF775 | c.1423C>G p.P475A | Missense Mutation (SNP) | VAF 32/578 reads (6%) | SIFT tolerated (0.85); PolyPhen benign (0.024); called by muse, mutect2
- ASTN2 | c.1108C>T p.L370= | Silent (SNP) | VAF 48/333 reads (14%) | called by muse, mutect2, varscan2
- CADPS2 | c.2169T>G p.S723= | Silent (SNP) | VAF 25/104 reads (24%) | called by muse, mutect2, varscan2
- CELSR2 | c.2682G>A p.V894= | Silent (SNP) | VAF 30/485 reads (6%) | catalogued as rs751488741; called by muse, mutect2
- CHD8 | c.792C>T p.A264= | Silent (SNP) | VAF 12/160 reads (8%) | catalogued as rs1271932427; called by muse, mutect2
- COL14A1 | c.2997G>T p.V999= | Silent (SNP) | VAF 6/97 reads (6%) | called by muse, mutect2
- CPS1 | c.1404A>G p.S468= | Silent (SNP) | VAF 24/313 reads (8%) | called by muse, mutect2
- GM2A | c.471G>A p.L157= | Silent (SNP) | VAF 20/741 reads (3%) | catalogued as rs879230184; called by muse, mutect2
- PCED1A | c.732G>T p.R244= | Silent (SNP) | VAF 86/665 reads (13%) | called by muse, mutect2, varscan2
- SHROOM3 | c.3195C>G p.G1065= | Silent (SNP) | VAF 17/640 reads (3%) | called by muse, mutect2
- WDR45 | c.390C>T p.D130= (on ENST00000376372 / NM_001029896.2; = p.D131= on NM_007075.3) | Silent (SNP) | VAF 13/254 reads (5%) | called by muse, mutect2
- ZFP57 | c.324C>A p.V108= | Silent (SNP) | VAF 18/576 reads (3%) | called by muse, mutect2
- ACSF3 | c.1366+3319C>T | Intron (SNP) | VAF 9/129 reads (7%) | catalogued as rs769747304; called by muse, mutect2
- BANP | c.1345-227G>C | Intron (SNP) | VAF 16/310 reads (5%) | called by muse, mutect2
- CCNC | c.798-659C>G | Intron (SNP) | VAF 40/176 reads (23%) | called by muse, mutect2, varscan2
- KRBOX4 | c.-15C>A | 5'UTR (SNP) | VAF 36/170 reads (21%) | catalogued as COSV53343437; called by muse, mutect2, varscan2
- MEG3 | n.1237C>G | RNA (SNP) | VAF 22/284 reads (8%) | called by muse, mutect2
- MRPL11 | c.473+252G>C | Intron (SNP) | VAF 34/230 reads (15%) | called by muse, mutect2, varscan2
- PEG10 | c.*681G>C | 3'UTR (SNP) | VAF 29/330 reads (9%) | called by muse, mutect2
- RPL23 | c.13+224G>C | Intron (SNP) | VAF 90/296 reads (30%) | called by muse, mutect2, varscan2
- SCN4B | c.*215C>A | 3'UTR (SNP) | VAF 25/308 reads (8%) | called by muse, mutect2
- SLC22A11 | c.1058+239G>A | Intron (SNP) | VAF 21/163 reads (13%) | called by muse, mutect2, varscan2
- SLC2A8 | c.*203G>C | 3'UTR (SNP) | VAF 18/127 reads (14%) | called by muse, mutect2, varscan2
